Surgical pathology report (de-identified scan), TCGA case TCGA-D6-A4ZB, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D6-A4ZB-01A (Primary Tumor).

Department of Cancer Pathology

Gender: **M**

Examination result

100-6-3

carcinoma, squamous cell, Keratinizing,
nos 8071/3

Clinical diagnosis (suspicion) **tumour of the larynx. Please mark the margins.**

Path: Site: largnx, nos C32.9

CQCF: Tongue, NOS C02.9

hw
11/5/12

Material:

1) Material: larynx, Method of collection: Collection of specimens for laboratory examination

Histopathological diagnosis:

Invasive keratinizing squamous carcinoma of the larynx and carcinoma in situ (G2, pT2)

Carcinoma planoepitheliale keratodes invasivum et in situ laryngis. G2, pT2.

Macroscopic description:

Surgical specimen sized 9.5 x 7.5 x 6cm, including larynx with the hyoid bone and part of the trachea 1.5 cm in length. Tumour sized 2.5 x 2.5 in the glottis region, infiltrating the supraglottal region and the anterior commissure.

Microscopic description:

Carcinoma planoepitheliale keratodes invasivum G2.

The tumour infiltrates all levels of the larynx, the aryepiglottic fold on the left side and the anterior commissure region.

Surgical incision lines off cancer invaded area. No signs of vascular, nerve and cartilage invasion found.

Assistant:

Results of intraoperative examination:

Result of intraoperative examination: Surgical incision lines free of cancer invasion. Final reply to be given after full material is developed

Assistant:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Time Relativity History		X
Time Synchronous Primary Metast		X
Level of Analysis		

10/31/12

Source: NCI Genomic Data Commons file 9cf83a68-74a3-4276-a284-e4af931aee47 (TCGA-D6-A4ZB.C47A153B-01FE-497A-AF09-E79AB1F8D0F1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).